Somatic mutation profile of tumor specimen 0DLX58 from CCDI case PBBZUL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.4 years (5,978 days).
Specimen 0DLX58: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d231b806-0273-4e88-bb4c-88cccfbb4a0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b84519b1-1fd8-442c-bb1d-4016ea328397

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Intron 4, 3'UTR 4, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, In Frame Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC5 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 87/726 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99192451; called by muse, mutect2, varscan2
- ARMH1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 165/1298 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1219316962; called by muse, mutect2, varscan2
- DNAH6 | c.7756C>T p.R2586W | Missense Mutation (SNP) | VAF 626/1253 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754179684, COSV52890071; called by muse, mutect2, varscan2
- EPHB4 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 96/751 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs751727413; called by muse, mutect2, varscan2
- FER1L6 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 82/770 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs991815242, COSV101206171; called by muse, mutect2, varscan2
- GAA | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 254/526 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV56406854; called by mutect2, varscan2
- GOPC | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 492/1176 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50004989; called by muse, mutect2, varscan2
- ITPKC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 673/1507 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs904288189, COSV54573896; called by muse, mutect2, varscan2
- MALRD1 | c.1849G>C p.V617L | Missense Mutation (SNP) | VAF 461/1005 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs532068703; called by muse, mutect2, varscan2
- MYH6 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 57/757 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV62454234; called by muse, mutect2
- PLEKHG4B | c.3466C>T p.R1156* (on ENST00000283426; = p.R1512* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 304/724 reads (42%) | catalogued as rs754687259; called by muse, mutect2
- SLC24A2 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 606/1343 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757235686, COSV53871834; called by muse, mutect2, varscan2
- SMAD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 102/1175 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV100129747; called by muse, mutect2
- STMND1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 755/1678 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as rs1301299694; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 54/1856 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CMYA5 | c.11908G>C p.G3970R | Missense Mutation (SNP) | VAF 296/649 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CNN2 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 165/451 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- DDX6 | c.1182_1184dup p.T395dup | In Frame Ins (INS) | VAF 206/580 reads (36%) | called by pindel, varscan2
- DNAJC13 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 278/665 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GMPR2 | c.291+1G>A p.X97_splice (on ENST00000355299 / NM_001351022.2; = p.X115_splice on NM_016576.5) | Splice Site (SNP) | VAF 295/683 reads (43%) | called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 58/1821 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IL1RL2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 36/1478 reads (2%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2
- KCNH3 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 37/1101 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- NUP98 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 592/1322 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- OR10A3 | c.896G>T p.R299M | Missense Mutation (SNP) | VAF 646/1400 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PXDN | c.591C>A p.D197E | Missense Mutation (SNP) | VAF 534/1112 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SMAD2 | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 131/1004 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SMAD2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 552/1036 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SP100 | c.1058-6G>A | Splice Region (SNP) | VAF 79/441 reads (18%) | called by muse, mutect2, varscan2
- TGFBR1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 66/746 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TIPARP | c.218T>A p.F73Y | Missense Mutation (SNP) | VAF 149/1178 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- VPS13C | c.2458C>T p.Q820* (on ENST00000644861 / NM_020821.3; = p.Q777* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 36/993 reads (4%) | called by muse, mutect2
- ARHGAP22 | c.2017T>C p.L673= | Silent (SNP) | VAF 562/1260 reads (45%) | catalogued as rs758122847; called by muse, mutect2, varscan2
- CMYA5 | c.11907A>C p.A3969= | Silent (SNP) | VAF 294/646 reads (46%) | called by muse, mutect2, varscan2
- FHL2 | c.726G>A p.R242= | Silent (SNP) | VAF 457/1007 reads (45%) | called by muse, varscan2
- IZUMO1R | c.99C>T p.H33= | Silent (SNP) | VAF 141/1054 reads (13%) | called by muse, mutect2, varscan2
- LRFN4 | c.1287C>T p.A429= | Silent (SNP) | VAF 101/730 reads (14%) | catalogued as rs781135899; called by muse, mutect2, varscan2
- NCKAP5L | c.879C>G p.A293= | Silent (SNP) | VAF 46/924 reads (5%) | called by muse, mutect2
- ZNF317 | c.1338C>T p.Y446= | Silent (SNP) | VAF 379/875 reads (43%) | catalogued as rs756906379; called by muse, varscan2
- C8orf48 | c.*56C>T | 3'UTR (SNP) | VAF 37/306 reads (12%) | catalogued as rs558942676; called by muse, mutect2, varscan2
- C9orf85 | c.323+1277A>G | Intron (SNP) | VAF 16/261 reads (6%) | catalogued as rs1446441319, COSV58253961; called by muse, mutect2
- CACNB4 | c.-14G>C | 5'UTR (SNP) | VAF 71/237 reads (30%) | called by muse, mutect2, varscan2
- GCGR | c.*48G>A | 3'UTR (SNP) | VAF 60/477 reads (13%) | catalogued as rs571884193; called by muse, mutect2, varscan2
- GCSAML | c.140-39T>C | Intron (SNP) | VAF 71/1774 reads (4%) | called by muse, mutect2
- INTS7 | c.-49T>A | 5'UTR (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
- MUC15 | c.-38-1184A>T | Intron (SNP) | VAF 70/786 reads (9%) | called by muse, mutect2
- NRF1 | c.*91G>A | 3'UTR (SNP) | VAF 144/292 reads (49%) | catalogued as rs953259407, COSV56213286; called by muse, mutect2, varscan2
- PIEZO2 | chr18:10671479 A>G | 3'Flank (SNP) | VAF 53/412 reads (13%) | catalogued as COSV53295939; called by muse, mutect2, varscan2
- SLC16A13 | c.199+12G>A | Intron (SNP) | VAF 111/1176 reads (9%) | called by muse, mutect2
- TMEM67 | c.*95T>C | 3'UTR (SNP) | VAF 92/292 reads (32%) | called by muse, varscan2
